Somatic mutation profile of tumor specimen MP2PRT-PAUWRU-TMP1-A (aliquot MP2PRT-PAUWRU-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAUWRU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,522 days).
Specimen MP2PRT-PAUWRU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1535ea41-37f9-410c-8657-1677c8d6a782.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUWRU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUWRU-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c23194c0-ba7b-4108-a689-13ec419e65ca

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, In Frame Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.5039_5041del p.S1680del | In Frame Del (DEL) | VAF 128/376 reads (34%) | hotspot (GDC flag); catalogued as rs587783502; called by pindel, varscan2
- PTPN11 | c.923A>G p.N308S | Missense Mutation (SNP) | VAF 92/228 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs121918455, CM021135, CM044252, COSV61006976, COSV61014185; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRWD3 | c.2719_2721del p.K908del | In Frame Del (DEL) | VAF 84/209 reads (40%) | catalogued as rs1185048077; called by pindel, varscan2
- DNAH6 | c.10702C>T p.R3568W | Missense Mutation (SNP) | VAF 72/152 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs775699338, COSV52862885; called by muse, mutect2, varscan2
- FTHL17 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 27/505 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.485); catalogued as rs1348661585, COSV63267923, COSV63268194; called by muse, mutect2
- WRAP73 | c.1047C>T p.N349= | Splice Region (SNP) | VAF 54/145 reads (37%) | catalogued as rs114947482; called by muse, mutect2, varscan2
